Somatic mutation profile of tumor specimen TCGA-B1-A47M-01A (aliquot TCGA-B1-A47M-01A-11D-A25F-10) from TCGA case TCGA-B1-A47M, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 79.6 years (29,068 days).
Specimen TCGA-B1-A47M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612d287e-fe0c-4e48-94e9-274a9ff70991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A47M-10A (Blood Derived Normal), aliquot TCGA-B1-A47M-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82d7c252-7b57-414c-bf60-f40547ccb073

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 23, Frame Shift Del 13, Nonsense Mutation 4, 3'UTR 3, Frame Shift Ins 3, Splice Region 2, Translation Start Site 1, 5'UTR 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.239C>A p.T80K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553487947, COSV67960012, COSV67960020, COSV67960088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.5039T>A p.V1680D (on ENST00000303395 / NM_001202435.3; = p.V1669D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553520380, COSV57669405, COSV57687049; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.268); catalogued as COSV62791731; called by muse, mutect2, varscan2
- AFF1 | c.3153C>T p.C1051= | Splice Region (SNP) | VAF 32/109 reads (29%) | catalogued as COSV57123998; called by muse, mutect2, varscan2
- AP2A1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs749327119, COSV62820973; called by muse, mutect2, varscan2
- ARL2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs758628032, COSV55861855; called by muse, mutect2
- ARL2BP | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV54656766; called by muse, mutect2, varscan2
- ATP10A | c.738C>T p.C246= | Splice Region (SNP) | VAF 37/95 reads (39%) | catalogued as COSV63524020; called by muse, mutect2, varscan2
- C18orf21 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV52449987; called by muse, mutect2, varscan2
- C4BPB | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV54692736; called by muse, mutect2, varscan2
- CD58 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.472); catalogued as COSV59841998; called by muse, mutect2, varscan2
- CDC6 | c.314A>G p.K105R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV52931439; called by muse, mutect2
- CDH6 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54078171; called by muse, mutect2, varscan2
- COL10A1 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54574667; called by muse, mutect2, varscan2
- COL6A3 | c.6773G>C p.G2258A | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1358585617, COSV55109196; called by muse, mutect2, varscan2
- CRB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.382); catalogued as COSV66348462; called by muse, mutect2, varscan2
- CTNNAL1 | c.266T>G p.I89R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57705518; called by muse, mutect2, varscan2
- CTNNAL1 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751084523, COSV57705527; called by muse, mutect2, varscan2
- CUL9 | c.6091T>C p.S2031P | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV52734534; called by muse, mutect2, varscan2
- DELE1 | c.1177A>C p.I393L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV52006578; called by muse, mutect2, varscan2
- DTWD2 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759774875, COSV58366363; called by muse, mutect2, varscan2
- DYRK1A | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.855); catalogued as COSV58710119; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs1377283633; called by pindel, varscan2
- FAM13B | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as COSV50373912; called by muse, mutect2, varscan2
- FAM149A | c.2322A>T p.*774Cext*33 (on ENST00000356371 / NM_001367768.2; = p.*483Cext*33 on NM_015398.3 and 3 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV57030335; called by muse, mutect2, varscan2
- FAM71B | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV57230715, COSV57231180; called by muse, mutect2, varscan2
- FBXO33 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV53235983; called by muse, mutect2, varscan2
- FER1L6 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 43/117 reads (37%) | catalogued as rs535471573, COSV67552766; called by muse, mutect2, varscan2
- GALC | c.1560T>G p.I520M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54330150; called by muse, mutect2
- GNL2 | c.1007G>A p.C336Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66081777; called by muse, mutect2, varscan2
- HDAC5 | c.2546C>G p.A849G | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV56821875; called by muse, mutect2, varscan2
- IGKV3-15 | c.336T>G p.N112K | Missense Mutation (SNP) | VAF 105/699 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1419982965; called by muse, varscan2
- IL10RA | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV57142084; called by muse, mutect2, varscan2
- IL1RL2 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs776005558, COSV51818813; called by muse, mutect2, varscan2
- ILKAP | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54520266; called by muse, mutect2, varscan2
- JAG1 | c.650A>C p.N217T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV54762722; called by muse, mutect2, varscan2
- JARID2 | c.2990T>C p.V997A | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59197732; called by muse, varscan2
- KASH5 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV71358456; called by muse, mutect2, varscan2
- KIAA1109 | c.766A>T p.N256Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52691748; called by muse, mutect2, varscan2
- LGALS3BP | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53166109; called by muse, mutect2, varscan2
- LPAR4 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.115); catalogued as COSV70913410; called by muse, mutect2, varscan2
- LRCH3 | c.1725C>G p.D575E | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV58396744; called by muse, mutect2, varscan2
- MYT1 | c.2023A>G p.K675E | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV60513299; called by muse, mutect2, varscan2
- NDOR1 | c.1744C>G p.L582V (on ENST00000371521 / NM_001144026.3; = p.L566V on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV61290000; called by muse, mutect2
- NF2 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58520457, COSV58530708; called by muse, mutect2, varscan2
- NOL11 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs370393293; called by muse, mutect2
- PEX12 | c.256T>G p.F86V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56778934; called by muse, mutect2, varscan2
- PRUNE2 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 34/66 reads (52%) | catalogued as COSV65047802; called by muse, mutect2, varscan2
- R3HDM1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51532641; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62926107; called by muse, mutect2, varscan2
- RPS6KC1 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV65302809; called by muse, mutect2, varscan2
- SAMD13 | c.106G>T p.V36L (on ENST00000370671; = p.V30L on NM_001010971.3) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV65744854, COSV65745513; called by muse, mutect2, varscan2
- SLC35A2 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54431774; called by muse, mutect2, varscan2
- SMARCA5 | c.1415A>C p.Y472S | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV51647274; called by muse, mutect2, varscan2
- SMC3 | c.2926T>A p.L976I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV62422312; called by muse, mutect2, varscan2
- SUGP1 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53238156; called by muse, mutect2, varscan2
- TRMT10C | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV59306949; called by muse, mutect2, varscan2
- TTR | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM971541, COSV52702079; called by muse, mutect2, varscan2
- USP32 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56277296; called by muse, mutect2, varscan2
- VHLL | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV60555013; called by muse, mutect2, varscan2
- VRTN | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV56443605; called by mutect2, varscan2
- WASHC2C | c.3019G>C p.G1007R (on ENST00000336378; = p.G986R on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100314174; called by muse, mutect2, varscan2
- WNK2 | c.6716C>T p.P2239L (on ENST00000297954 / NM_001282394.1; = p.P2202L on NM_006648.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.024); catalogued as rs377748076, COSV99943771; called by muse, mutect2, varscan2
- ZBTB6 | c.466A>G p.N156D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1425556060, COSV65410637; called by muse, mutect2
- ZDHHC5 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.775); catalogued as COSV54709185; called by muse, mutect2, varscan2
- ZNF567 | c.1075C>T p.H359Y (on ENST00000536254 / NM_001322913.1; = p.H328Y on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62446503; called by muse, mutect2, varscan2
- ZNF569 | c.779A>G p.H260R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57599071; called by muse, mutect2, varscan2
- ZNF880 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as COSV69906865; called by muse, mutect2, varscan2
- ZSCAN25 | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV53554622; called by muse, mutect2, varscan2
- ADAM20 | c.746_747del p.E249Gfs*2 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- CLK4 | c.1381dup p.T461Nfs*8 | Frame Shift Ins (INS) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- CTCFL | c.737del p.N246Ifs*31 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- ERRFI1 | c.524_525del p.T175Kfs*15 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | called by mutect2, pindel, varscan2
- FAM117B | c.688del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- IGKV3D-15 | c.336T>G p.N112K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by mutect2, varscan2
- INPP5B | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2
- NAB2 | c.1163del p.P388Lfs*46 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- ODF2 | c.1533del p.K512Rfs*21 (on ENST00000434106 / NM_153433.2; = p.K488Rfs*21 on NM_002540.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- OSMR | c.1836A>C p.L612F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- PARG | c.2699del p.F900Sfs*8 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by pindel, varscan2
- PCDHB10 | c.368_371del p.V123Gfs*3 | Frame Shift Del (DEL) | VAF 46/144 reads (32%) | called by pindel, varscan2
- SLC25A15 | c.621del p.G208Afs*5 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- SMARCB1 | c.929_930insTT p.T311* (on ENST00000263121; = p.T357* on NM_003073.5) | Frame Shift Ins (INS) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- TAS2R14 | c.319del p.Y107Ifs*5 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- TDRD15 | c.5279A>C p.K1760T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TET1 | c.5247del p.Q1749Hfs*13 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- TEX9 | c.756del p.K252Nfs*23 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- TSHZ1 | c.2105_2106insA p.K703Qfs*26 (on ENST00000580243 / NM_001308210.2; = p.K658Qfs*26 on NM_005786.6) | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | called by mutect2, pindel*, varscan2
- ABHD5 | c.480T>C p.A160= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV50007044; called by muse, mutect2, varscan2
- BNIP5 | c.918C>G p.S306= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV71325844; called by muse, mutect2, varscan2
- CALM1 | c.378C>T p.I126= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV63663730; called by muse, mutect2, varscan2
- CCDC191 | c.2613C>T p.I871= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV55676237; called by muse, mutect2
- CHPF | c.1617T>A p.A539= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV60536690; called by muse, mutect2, varscan2
- DOCK9 | c.4824C>T p.S1608= (on ENST00000376460 / NM_001366676.2; = p.S1609= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV59643167; called by muse, mutect2, varscan2
- EYA1 | c.1011C>T p.H337= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV58173876; called by muse, mutect2, varscan2
- KCTD11 | c.477C>T p.D159= (on ENST00000333751 / NM_001363642.1; = p.D120= on NM_001002914.2) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs79616684, COSV50141628; called by muse, mutect2, varscan2
- KCTD8 | c.207T>A p.T69= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV63596258; called by muse, mutect2, varscan2
- KLHL12 | c.873C>T p.S291= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV66128083; called by muse, mutect2, varscan2
- L2HGDH | c.1380A>G p.R460= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV55560644; called by muse, mutect2, varscan2
- LAMA5 | c.3264C>T p.I1088= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV53372068; called by muse, mutect2, varscan2
- MSR1 | c.774T>C p.D258= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV50534655; called by muse, varscan2
- NF2 | c.402T>C p.P134= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV58521345, COSV58530726; called by muse, mutect2, varscan2
- OGA | c.2145T>C p.Y715= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV63383319; called by muse, mutect2, varscan2
- POGZ | c.2079C>T p.S693= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs755065616, COSV55042005; called by muse, mutect2, varscan2
- RABAC1 | c.411C>A p.G137= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV55771339; called by muse, mutect2, varscan2
- SECISBP2L | c.2043T>G p.V681= (on ENST00000559471 / NM_001193489.2; = p.V636= on NM_014701.4) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV55937790; called by muse, mutect2, varscan2
- TDRD7 | c.1518T>G p.P506= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV62431040; called by muse, mutect2, varscan2
- TLR5 | c.13C>T p.L5= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs1020165611, COSV60559389; called by muse, mutect2, varscan2
- TRIB2 | c.183C>A p.I61= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV50230889; called by muse, mutect2, varscan2
- VIPR2 | c.798A>G p.L266= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as rs1165530474, COSV51118077; called by muse, mutect2, varscan2
- ZNF567 | c.1074T>A p.T358= (on ENST00000536254 / NM_001322913.1; = p.T327= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV62446491; called by muse, mutect2, varscan2
- C2orf88 | c.*1222A>T | 3'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100502916; called by muse, varscan2
- KCNJ12 | chr17:21417617 del AGG | 3'Flank (DEL) | VAF 24/72 reads (33%) | called by pindel, varscan2
- LRRN2 | c.-506G>A | 5'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2
- SOX1 | c.*2686C>T | 3'UTR (SNP) | VAF 24/66 reads (36%) | catalogued as rs745352809; called by muse, mutect2, varscan2
- ZNF22 | c.*1129A>G | 3'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100026652; called by muse, mutect2, varscan2
